Somatic mutation profile of tumor specimen TCGA-14-4157-01A (aliquot TCGA-14-4157-01A-01D-1353-08) from TCGA case TCGA-14-4157, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 40.6 years (14,816 days).
Specimen TCGA-14-4157-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08243a6d-9f72-475f-acd7-1d9c268cc648.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-4157-10A (Blood Derived Normal), aliquot TCGA-14-4157-10A-01D-1353-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/487c7329-c5ca-4921-954a-5347082144b4

The open-access MAF lists 32 somatic variants for this specimen: 28 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 23, Silent 4, Frame Shift Del 2, Nonsense Mutation 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 49/142 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 36/74 reads (49%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- TP53 | c.470T>G p.V157G | Missense Mutation (SNP) | VAF 50/108 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM138009, CM161671, COSV52675572, COSV52699845, COSV52722122; called by muse, varscan2
- ATRX | c.3637del p.Q1213Rfs*4 | Frame Shift Del (DEL) | VAF 104/150 reads (69%) | catalogued as COSV64872066; called by mutect2, pindel, varscan2
- CDKN2AIP | c.529A>G p.T177A | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV56627129; called by muse, mutect2, varscan2
- DAB1 | c.653A>T p.N218I | Missense Mutation (SNP) | VAF 105/267 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV59727113; called by muse, mutect2, varscan2
- DNAH8 | c.2831T>C p.V944A | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV59436810, COSV59442453; called by muse, varscan2
- FFAR2 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.313); catalogued as rs775045094, COSV55832218; called by muse, mutect2, varscan2
- FOSL2 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.166); catalogued as COSV53104328; called by muse, mutect2, varscan2
- FSHR | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1328627478, COSV58622724; called by muse, mutect2
- HSPG2 | c.1495G>A p.V499I | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376748881; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP3 | c.1747C>T p.R583C | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748288353, COSV53503748; called by muse, mutect2, varscan2
- OR4C15 | c.1045C>G p.Q349E (on ENST00000314644; = p.Q295E on NM_001001920.2) | Missense Mutation (SNP) | VAF 76/198 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV58952568; called by muse, mutect2, varscan2
- PDIA3 | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 153/327 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1338827291, COSV55855775; called by muse, mutect2, varscan2
- PRPF6 | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs763264227, COSV53869908; called by muse, mutect2, varscan2
- PRXL2C | c.272T>C p.V91A | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs374719525; called by muse, mutect2, varscan2
- RAP2B | c.124A>G p.K42E | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60256943; called by muse, mutect2
- RP1 | c.961A>G p.K321E | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55115824; called by muse, mutect2, varscan2
- SLC9A2 | c.500G>C p.G167A | Missense Mutation (SNP) | VAF 48/644 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52131571, COSV52135457; called by muse, mutect2
- SPTBN5 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.604); catalogued as COSV58020031; called by muse, mutect2, varscan2
- TAF15 | c.1333G>A p.G445S (on ENST00000605844 / NM_139215.3; = p.G442S on NM_003487.4) | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs757219694; called by muse, mutect2, varscan2
- TMEM260 | c.704A>G p.H235R | Missense Mutation (SNP) | VAF 299/682 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV55098733, COSV55099929; called by muse, mutect2, varscan2
- UCKL1 | c.549T>A p.Y183* | Nonsense Mutation (SNP) | VAF 194/465 reads (42%) | catalogued as COSV62402752; called by muse, mutect2, varscan2
- VAMP7 | c.489T>G p.N163K | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.16); catalogued as COSV52901603; called by muse, mutect2, varscan2
- ZNF207 | c.1213A>G p.M405V | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.006); catalogued as COSV58299744; called by muse, mutect2, varscan2
- ZNF283 | c.734T>A p.L245* | Nonsense Mutation (SNP) | VAF 54/92 reads (59%) | catalogued as COSV61031154; called by muse, mutect2, varscan2
- ANKLE2 | c.804_805del p.P269Cfs*8 | Frame Shift Del (DEL) | VAF 64/206 reads (31%) | called by pindel, varscan2
- GBP2 | c.1537_1539del p.E513del | In Frame Del (DEL) | VAF 54/132 reads (41%) | called by pindel, varscan2
- ADAMTSL3 | c.219C>T p.D73= | Silent (SNP) | VAF 64/154 reads (42%) | catalogued as COSV54446146; called by muse, mutect2, varscan2
- CTNNA2 | c.354A>C p.V118= | Silent (SNP) | VAF 52/150 reads (35%) | catalogued as COSV63563340; called by muse, mutect2, varscan2
- KRT80 | c.1260G>A p.K420= | Silent (SNP) | VAF 64/130 reads (49%) | catalogued as rs773092935, COSV57548791; called by muse, mutect2, varscan2
- LRIG3 | c.2337C>T p.N779= | Silent (SNP) | VAF 71/151 reads (47%) | catalogued as rs376403609; called by muse, mutect2, varscan2
